Gene-level copy-number profile of tumor specimen TCGA-B2-3924-01B from TCGA case TCGA-B2-3924, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 73.5 years (26,846 days).
Specimen TCGA-B2-3924-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRC.9070ab00-7976-4b1f-a278-a2f9c67aa6df.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B2-3924-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 357 have no estimate.
https://portal.gdc.cancer.gov/files/83d8002d-b6ae-4036-8d3e-bc039536f79e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 2,395; copy number 2: 57,537; copy number 3: 266; copy number 4: 28; copy number 5: 25; copy number 6: 5; copy number 7: 2; copy number 8: 1; copy number 9: 1; copy number 12: 1; copy number 15: 2.
ABSOLUTE estimates for another vial of this sample (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B2-3924-01A-02D-A274-01): tumor purity 0.49, ploidy 2.09, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:73,209,746–73,263,196, 1 gene (within-gene range 0–2): AL365232.1.
- chr8:23,634,876–23,635,507, 1 gene: SINHCAFP3.
- chr20:50,958,818–50,963,929, 1 gene: MOCS3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 37 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:51,541,144–51,668,667, 2 genes, copy number 5 (within-gene range 2–5): RAD54L2, RNU6ATAC29P.
- chr7:62,275,361–62,275,678, 1 gene, copy number 8: AC128676.1.
- chr7:101,195,007–101,252,316, 7 genes, copy number 5: MOGAT3, DGAT2L7P, RPSAP46, PLOD3, ZNHIT1, CLDN15, FIS1.
- chr11:102,295,060–102,295,806, 1 gene, copy number 5: AP000942.1.
- chr12:48,350,945–48,442,411, 1 gene, copy number 6 (within-gene range 2–6): AC090115.1.
- chr12:48,385,417–48,442,947, 4 genes, copy number 6: OR5BT1P, OR5BJ1P, OR8S21P, OR8T1P.
- chr13:28,067,587–28,068,334, 1 gene, copy number 5: KATNBL1P1.
- chr13:48,316,863–48,328,564, 2 genes, copy number 15: PPP1R26P1, PCNPP5.
- chr14:70,906,657–70,907,111, 1 gene, copy number 9: AC004825.2.
- chr18:35,591,737–35,597,599, 2 genes, copy number 7: MIR3975, AC090220.1.
- chr19:21,997,648–21,998,840, 1 gene, copy number 12: BNIP3P28.
- chr19:58,305,319–58,381,030, 14 genes, copy number 5: ERVK3-1, AC010642.2, AC010642.1, ZSCAN22, MIR6806, A1BG, AC012313.3, A1BG-AS1, AC012313.10, ZNF497, AC012313.2, AC012313.6, RNA5SP473, ZNF837.

Autosomal genes at a single copy (total copy number 1): 32. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
